CCDI case PBBNEE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/c332db62-da69-4ef2-b8af-f62db133fa3c

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 14.1 years (5,165 days).

Biospecimens (3 samples)
- Sample 0DDKDO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDKE0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DDKE1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
